MMRF case MMRF_2519 — Multiple Myeloma CoMMpass Study (MMRF-COMMPASS)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Plasma Cell Tumors; Primary site: Hematopoietic and reticuloendothelial systems. Index date (day 0 for every day count below): first treatment.
https://portal.gdc.cancer.gov/cases/b5d9c7af-3926-4a3f-a52b-9ae6e2255c5a

Demographics
Sex at birth: male; Race: white; Ethnicity: hispanic or latino; Age at index: 67 years; Vital status: Alive.

Diagnoses (1)
1. Multiple myeloma: ICD-O-3 morphology code: 9732/3; Tissue or organ of origin: Bone marrow; Site of resection or biopsy: Bone marrow; Age at diagnosis: 67.5 years (24,648 days); ISS stage: I; Days to last known disease status: 696 days (1.9 years); Days to last follow up: 696 days (1.9 years).
   Treatment given: Therapeutic agents: Bortezomib + Dexamethasone + Thalidomide; Regimen or line of therapy: First line of therapy; Days to treatment start: 1 day.
   Treatment given: Treatment type: Stem Cell Transplantation, Autologous; Regimen or line of therapy: First line of therapy; Days to treatment start: 186 days; Days to treatment end: 186 days.

Molecular and laboratory tests (laboratory values one line per visit day; values rounded to 3 significant figures where GDC's unit conversion carried more)
- Day -17 (ECOG 1): M Protein 2.45 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 46.7 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 5.9 mg/dL; Immunoglobulin G 30.3 g/L; Immunoglobulin A 0.45 g/L; Immunoglobulin M 0.11 g/L; Beta 2 Microglobulin 2.59 µg/mL; Lactate Dehydrogenase 2.25 µkat/L; Hemoglobin 8.18 mmol/L; Leukocytes 3.42 ×10⁹/L; Absolute Neutrophil 1.47 ×10⁹/L; Platelets 173 ×10⁹/L; Creatinine 83.1 µmol/L; Calcium 2.45 mmol/L; Albumin 39.6 g/L; Total Protein 8.3 g/dL; Glucose 6.11 mmol/L; C-Reactive Protein 0.09 mg/dL.
- Day 87 (ECOG 1): M Protein 0.41 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 1.29 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.84 mg/dL; Immunoglobulin G 9.33 g/L; Immunoglobulin A 0.68 g/L; Immunoglobulin M 0.13 g/L; Beta 2 Microglobulin 2.25 µg/mL; Lactate Dehydrogenase 3.8 µkat/L; Hemoglobin 8.56 mmol/L; Leukocytes 4.27 ×10⁹/L; Absolute Neutrophil 2.53 ×10⁹/L; Platelets 97.5 ×10⁹/L; Creatinine 79.6 µmol/L; Blood Urea Nitrogen 2.18 mmol/L; Calcium 2.38 mmol/L; Albumin 43.3 g/L; Total Protein 6.1 g/dL; Glucose 5.45 mmol/L.
- Day 171 (ECOG 0): M Protein 0.19 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 1.12 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.58 mg/dL; Immunoglobulin G 5.73 g/L; Immunoglobulin A 0.48 g/L; Immunoglobulin M 0.12 g/L; Lactate Dehydrogenase 3.78 µkat/L; Hemoglobin 8.87 mmol/L; Leukocytes 5.3 ×10⁹/L; Absolute Neutrophil 3.25 ×10⁹/L; Platelets 153 ×10⁹/L; Creatinine 72.5 µmol/L; Calcium 2.3 mmol/L; Albumin 39.5 g/L; Total Protein 6.07 g/dL; Glucose 6.22 mmol/L.
- Day 253 (ECOG 0): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 0.79 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.77 mg/dL; Immunoglobulin G 9.55 g/L; Immunoglobulin A 0.79 g/L; Immunoglobulin M 0.11 g/L; Beta 2 Microglobulin 1.96 µg/mL; Hemoglobin 8.56 mmol/L; Leukocytes 4.26 ×10⁹/L; Absolute Neutrophil 2.06 ×10⁹/L; Platelets 162 ×10⁹/L; Creatinine 84 µmol/L; Blood Urea Nitrogen 1.89 mmol/L; Calcium 2.35 mmol/L; Albumin 43.7 g/L; Total Protein 6.53 g/dL; Glucose 7.26 mmol/L.
- Day 353 (ECOG 0): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 1.64 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 1.58 mg/dL; Immunoglobulin G 10.1 g/L; Immunoglobulin A 0.95 g/L; Immunoglobulin M 0.18 g/L; Beta 2 Microglobulin 2.09 µg/mL; Lactate Dehydrogenase 2.85 µkat/L; Hemoglobin 9.3 mmol/L; Leukocytes 4.96 ×10⁹/L; Absolute Neutrophil 3.16 ×10⁹/L; Platelets 149 ×10⁹/L; Creatinine 91.9 µmol/L; Blood Urea Nitrogen 2 mmol/L; Calcium 2.43 mmol/L; Albumin 43.9 g/L; Total Protein 6.67 g/dL; Glucose 6.49 mmol/L.
- Day 423 (ECOG 0): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 1.57 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 1.67 mg/dL; Immunoglobulin G 14 g/L; Immunoglobulin A 1.13 g/L; Immunoglobulin M 0.24 g/L; Beta 2 Microglobulin 2.24 µg/mL; Lactate Dehydrogenase 2.58 µkat/L; Hemoglobin 8.99 mmol/L; Leukocytes 5.26 ×10⁹/L; Absolute Neutrophil 2.92 ×10⁹/L; Platelets 156 ×10⁹/L; Creatinine 110 µmol/L; Blood Urea Nitrogen 2.11 mmol/L; Calcium 2.45 mmol/L; Albumin 43.2 g/L; Total Protein 6.66 g/dL; Glucose 6.05 mmol/L.
- Day 535 (ECOG 0): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 1.34 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 1.47 mg/dL; Immunoglobulin G 10.7 g/L; Immunoglobulin A 1.11 g/L; Immunoglobulin M 0.35 g/L; Beta 2 Microglobulin 2.16 µg/mL; Hemoglobin 9.3 mmol/L; Leukocytes 5.04 ×10⁹/L; Absolute Neutrophil 2.98 ×10⁹/L; Platelets 175 ×10⁹/L; Creatinine 91.9 µmol/L; Blood Urea Nitrogen 1.75 mmol/L; Calcium 2.35 mmol/L; Albumin 44.3 g/L; Total Protein 6.53 g/dL; Glucose 6.05 mmol/L.
- Day 619 (ECOG 0): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 2.56 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 1.48 mg/dL; Immunoglobulin G 11.3 g/L; Immunoglobulin A 1.38 g/L; Immunoglobulin M 0.27 g/L; Beta 2 Microglobulin 2.32 µg/mL; Lactate Dehydrogenase 2.85 µkat/L; Hemoglobin 9.49 mmol/L; Leukocytes 5.16 ×10⁹/L; Absolute Neutrophil 2.97 ×10⁹/L; Platelets 166 ×10⁹/L; Creatinine 88.4 µmol/L; Blood Urea Nitrogen 4.67 mmol/L; Calcium 2.38 mmol/L; Albumin 43.8 g/L; Total Protein 6.81 g/dL; Glucose 6.99 mmol/L.
- Day 696 (ECOG 0): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 1.71 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 1.26 mg/dL; Immunoglobulin G 10.4 g/L; Immunoglobulin A 1.2 g/L; Immunoglobulin M 0.21 g/L; Beta 2 Microglobulin 2.1 µg/mL; Lactate Dehydrogenase 1.78 µkat/L; Hemoglobin 9.05 mmol/L; Leukocytes 4.42 ×10⁹/L; Absolute Neutrophil 2.3 ×10⁹/L; Platelets 139 ×10⁹/L; Creatinine 86.6 µmol/L; Blood Urea Nitrogen 5.17 mmol/L; Calcium 2.4 mmol/L; Albumin 44.3 g/L; Total Protein 6.36 g/dL; Glucose 6.66 mmol/L.

Other clinical attributes
- Day -17: Weight: 103 kg; Height: 183 cm.

Family history
- Relative with cancer history: yes; Relationship type: Father; Relationship primary diagnosis: Lung Cancer; Relationship sex at birth: male.
- Relative with cancer history: yes; Relationship type: Mother; Relationship sex at birth: female.

Biospecimens (2 samples)
- Sample MMRF_2519_1_BM_CD138pos: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS; Days to sample procurement: -17 days.
- Sample MMRF_2519_1_PB_WBC: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood NOS; Days to sample procurement: -17 days.
